Somatic mutation profile of tumor specimen C3L-02041-02 (aliquot CPT0125510009) from CPTAC case C3L-02041, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.8 years (18,904 days).
Specimen C3L-02041-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) adaf900e-6d1c-4a69-bcbd-c57699e6e576.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02041-31 (Blood Derived Normal), aliquot CPT0124240002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/302b66ad-e708-408e-858d-62f139ded158

The open-access MAF lists 89 somatic variants for this specimen: 56 protein-altering or splice-affecting, 23 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 23, Intron 4, 3'UTR 3, Nonsense Mutation 3, Splice Site 2, 5'Flank 2, Frame Shift Del 2, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 69/336 reads (21%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 24/160 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN9A | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 28/245 reads (11%) | catalogued as rs377543079, COSV57602874; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 256/441 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANAPC7 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV71443897; called by muse, mutect2
- ARHGAP39 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 64/410 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1332156834, COSV52769887; called by muse, mutect2, varscan2
- DAPP1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV56452685; called by muse, mutect2
- EIF3A | c.2099G>A p.R700K | Missense Mutation (SNP) | VAF 62/283 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV64962881; called by muse, mutect2, varscan2
- FAM169A | c.955C>G p.H319D | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as COSV65846216; called by muse, varscan2
- FES | c.1946G>A p.R649H | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs779752765, COSV61000217; called by muse, mutect2, varscan2
- GALNT13 | c.1543C>T p.R515* | Nonsense Mutation (SNP) | VAF 40/162 reads (25%) | catalogued as rs780336642, COSV101222521; called by muse, mutect2, varscan2
- HCLS1 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 42/366 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as rs373119014; called by muse, mutect2, varscan2
- HDAC7 | c.712A>G p.T238A (on ENST00000427332; = p.T277A on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1244652092; called by muse, mutect2
- KBTBD13 | c.697C>A p.P233T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.144); catalogued as rs768422348; called by muse, mutect2
- LEFTY2 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 31/589 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs1385376520; called by muse, mutect2
- PIEZO2 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs957467830; called by muse, mutect2, varscan2
- PITX2 | c.793G>A p.A265T (on ENST00000354925 / NM_001204397.1; = p.A272T on NM_000325.6) | Missense Mutation (SNP) | VAF 132/662 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.878); catalogued as COSV60741982; called by muse, mutect2, varscan2
- PLXNA3 | c.3184G>A p.G1062S | Missense Mutation (SNP) | VAF 13/289 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.943); catalogued as COSV63755499; called by muse, mutect2
- RBM33 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as rs762099807; called by muse, mutect2, varscan2
- SCARF2 | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 150/490 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1228018827, COSV56733385; called by muse, mutect2, varscan2
- SLC30A7 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1445810167; called by muse, mutect2, varscan2
- STARD9 | c.11275G>A p.V3759M | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); catalogued as rs1199887229; called by muse, mutect2, varscan2
- TAF1L | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 35/670 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs768264023; called by muse, mutect2
- TNNI3 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 83/633 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); catalogued as COSV61277999; called by muse, mutect2, varscan2
- DCDC2 | c.1282G>C p.D428H | Missense Mutation (SNP) | VAF 9/253 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); called by muse, mutect2
- DUSP14 | c.542T>C p.V181A | Missense Mutation (SNP) | VAF 6/151 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- ERBIN | c.3190C>T p.R1064* | Nonsense Mutation (SNP) | VAF 40/606 reads (7%) | called by muse, mutect2
- FAM169A | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, varscan2
- GABRA1 | c.119C>G p.T40S | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); called by muse, mutect2
- GPR83 | c.1156A>T p.T386S | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.007); called by muse, mutect2
- HAND2 | c.555+1G>A p.X185_splice | Splice Site (SNP) | VAF 86/641 reads (13%) | called by muse, mutect2, varscan2
- HDAC6 | c.1553G>T p.G518V | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HTR1F | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 21/645 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGKV3D-20 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 90/643 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGLV2-11 | c.203_215delinsC p.M68_V72delinsT | In Frame Del (DEL) | VAF 105/938 reads (11%) | called by pindel, varscan2*
- KIF3B | c.488G>T p.R163M | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- LYSMD3 | c.764A>G p.D255G | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- MYL9 | c.450G>C p.K150N | Missense Mutation (SNP) | VAF 14/488 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.041); called by muse, mutect2
- NHS | c.4507A>G p.K1503E | Missense Mutation (SNP) | VAF 83/461 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NHSL2 | c.1699C>A p.P567T (on ENST00000510661; = p.P933T on NM_001013627.2) | Missense Mutation (SNP) | VAF 34/582 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.344); called by muse, mutect2
- OBSCN | c.17568C>A p.N5856K | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- OBSCN | c.19350C>A p.D6450E | Missense Mutation (SNP) | VAF 87/406 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAK1 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 32/369 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); called by muse, mutect2
- PLCE1 | c.4025C>A p.T1342N | Missense Mutation (SNP) | VAF 26/579 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); called by muse, mutect2
- PML | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 133/466 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PRSS33 | c.13T>C p.S5P | Missense Mutation (SNP) | VAF 43/332 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRM | c.3560A>C p.K1187T | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SELE | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOP3B | c.203-2A>G p.X68_splice | Splice Site (SNP) | VAF 50/610 reads (8%) | called by muse, mutect2
- TUBGCP5 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP47 | c.2280G>A p.M760I (on ENST00000399455 / NM_001372095.1; = p.M672I on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/159 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- WNK2 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 95/234 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZBBX | c.956A>G p.E319G | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZC3HAV1 | c.2148_2155del p.Q717Lfs*10 | Frame Shift Del (DEL) | VAF 23/253 reads (9%) | called by mutect2, pindel
- ZSCAN10 | c.1040G>A p.R347Q (on ENST00000252463; = p.R402Q on NM_032805.3) | Missense Mutation (SNP) | VAF 115/326 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ZZEF1 | c.1178_1199del p.D393Gfs*4 | Frame Shift Del (DEL) | VAF 121/798 reads (15%) | called by mutect2, pindel
- AGBL5 | c.1722G>A p.P574= | Silent (SNP) | VAF 76/752 reads (10%) | catalogued as rs146009281; called by muse, mutect2
- AHNAK | c.16428C>T p.V5476= | Silent (SNP) | VAF 43/307 reads (14%) | catalogued as rs765790397; called by muse, mutect2, varscan2
- CCNL1 | c.129C>T p.G43= | Silent (SNP) | VAF 84/508 reads (17%) | called by muse, mutect2, varscan2
- FOXA3 | c.285G>A p.P95= | Silent (SNP) | VAF 47/243 reads (19%) | catalogued as rs768299044; called by muse, mutect2, varscan2
- FZD3 | c.1794G>A p.T598= | Silent (SNP) | VAF 121/307 reads (39%) | catalogued as rs182719657; called by muse, mutect2, varscan2
- GPR39 | c.612C>T p.T204= | Silent (SNP) | VAF 25/245 reads (10%) | catalogued as COSV100258925; called by muse, mutect2
- GRXCR1 | c.501C>G p.R167= | Silent (SNP) | VAF 81/644 reads (13%) | catalogued as COSV101295706; called by muse, mutect2, varscan2
- HPSE2 | c.922C>A p.R308= | Silent (SNP) | VAF 36/504 reads (7%) | called by muse, mutect2
- HR | c.1575G>A p.E525= | Silent (SNP) | VAF 26/232 reads (11%) | catalogued as rs557921105; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LDB3 | c.1434C>T p.S478= | Silent (SNP) | VAF 19/274 reads (7%) | catalogued as rs1273006981; called by muse, mutect2
- MUC5AC | c.14766C>T p.S4922= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as rs748060750; called by muse, mutect2
- MYH13 | c.5268G>A p.E1756= | Silent (SNP) | VAF 79/474 reads (17%) | called by muse, mutect2, varscan2
- NEDD4L | c.306C>T p.D102= | Silent (SNP) | VAF 26/300 reads (9%) | catalogued as rs1295407360; called by muse, mutect2
- OAS3 | c.1482A>G p.A494= | Silent (SNP) | VAF 42/722 reads (6%) | catalogued as rs1391317168; called by muse, mutect2
- PARD3B | c.2322C>T p.G774= (on ENST00000406610 / NM_001302769.2; = p.G712= on NM_152526.6) | Silent (SNP) | VAF 24/287 reads (8%) | called by muse, mutect2
- PIK3R6 | c.594G>A p.Q198= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs1385735199; called by muse, mutect2, varscan2
- POM121L12 | c.687C>T p.F229= | Silent (SNP) | VAF 17/272 reads (6%) | catalogued as rs377744248, COSV68692454; called by muse, mutect2
- PRAMEF20 | c.660C>G p.V220= | Silent (SNP) | VAF 41/1412 reads (3%) | called by muse, mutect2
- SMYD3 | c.126G>A p.K42= | Silent (SNP) | VAF 49/234 reads (21%) | catalogued as rs951420728; called by muse, mutect2, varscan2
- SPATA5 | c.1308T>C p.R436= | Silent (SNP) | VAF 10/133 reads (8%) | called by muse, mutect2
- SWSAP1 | c.333C>T p.A111= (on ENST00000312423; = p.A132= on NM_175871.4) | Silent (SNP) | VAF 104/617 reads (17%) | catalogued as rs951538353; called by muse, mutect2, varscan2
- TUBG1 | c.630G>A p.L210= | Silent (SNP) | VAF 184/588 reads (31%) | catalogued as COSV99258328; called by muse, mutect2, varscan2
- ZNF460 | c.1008T>C p.F336= | Silent (SNP) | VAF 22/161 reads (14%) | called by muse, mutect2, varscan2
- AGPAT4 | c.348+4897G>A | Intron (SNP) | VAF 20/334 reads (6%) | called by muse, mutect2
- AP1S1 | chr7:101154461 G>C | 5'Flank (SNP) | VAF 21/568 reads (4%) | called by muse, mutect2
- DNM3 | c.1689+13266T>C | Intron (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
- DYSF | c.*28G>A | 3'UTR (SNP) | VAF 94/563 reads (17%) | catalogued as rs750084649, COSV50643871, COSV99251054; called by muse, mutect2, varscan2
- HEPACAM2 | c.*19G>C | 3'UTR (SNP) | VAF 8/203 reads (4%) | called by muse, mutect2
- POLR1B | c.178-1138G>A | Intron (SNP) | VAF 17/59 reads (29%) | catalogued as rs940767610; called by muse, mutect2, varscan2
- PSMD5 | chr9:120843267 C>T | 5'Flank (SNP) | VAF 22/149 reads (15%) | catalogued as rs1361452970; called by muse, mutect2, varscan2
- RUNX1 | c.*83G>A | 3'UTR (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- SACS | c.-52A>C | 5'UTR (SNP) | VAF 11/253 reads (4%) | called by muse, mutect2
- TRIOBP | c.6324+199G>A | Intron (SNP) | VAF 60/898 reads (7%) | called by muse, mutect2
